Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5JA, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5JA-01A (Primary Tumor).

[page 1 of 3]
Requesting Doctor's Information:

HISTOPATHOLOGY FOR REVIEW

Slides were reviewed as part of a study comparing CGH performed on fresh frozen tissue in benign and malignant adrenal cortical tumours.

I agree with diagnosis of adrenal cortical carcinoma.

Tumour Weight 865 g.

Wells criteria: All 9 from 9

Less than 25% clear cells

Necrosis

Diffuse Architecture

Venous invasion

Sinusoidal invasion

Capsular invasion

High nuclear grade

High mitotic rate

Atypical mitosis

FINAL DIAGNOSIS:

Adrenal: Adrenal cortical carcinoma

REPORTING PATHOLOGIST:

(Electronic Signature)

ICD-O-3

Carcinoma, Adrenal Cortical 8370/3

Site: Adrenal Gland, cortex C74.0

940 1/30/13

A
T
H
O
L
O
G
Y

A
N
A
T
O
M
I
C
A
L

P
A
T
H
O
L
O
G
Y

COPIES

[page 2 of 3]
D.O
SEX

Specimen : Specs. Multiple Type
Exams : Z 2 C5 FS1 IP4

CLINICAL HISTORY

Nodule from anterior duodenum ? met from adrenal tumour.

1. Torted appendix epiploicae transverse colon.
2. Rt adrenocortical tumour.
3. IVC invasive mass.

Addition tumour from crus of Rt diaphragm.

MACROSCOPIC

1. LABELLED 'NODULE ON FRONT OF DUODENUM'. A single 3mm biopsy. All embedded in one block.

Examined by frozen section and reported by Dr. as "No evidence of malignancy".

2. LABELLED 'RIGHT ADRENO CORTICAL CANCER'. A large tumour weighing 865g and measuring 150 x 100 x 100mm. The tumour is incompletely surrounded by fibrous capsules, has been previously opened and has a ragged haemorrhagic, variegated yellow grey nodular cut surface. Blocks: A-C tumour with capsule; D-K representative sections tumour.

3. LABELLED 'IVC INVASIVE MASS'. Two pieces of ragged tissue with an aggregate weight of 21g. They measure 55 x 35 x 25mm and 50 x 20 x 20mm. They have a ragged yellow grey cut surface. Representative sections in four blocks.

4. LABELLED 'ADDITIONAL TUMOUR FROM CRUS OF DIAPHRAGM'. A haemorrhagic tissue fragment measuring 23 x 15 x 10mm. All embedded in one block.

5. LABELLED 'TORTED APPENDIX EPIPLOICAE OF TRANSVERSE COLON'. A pedunculated grey mass with shiny grey serosal surface measuring 22 x 7 x 5mm. All embedded in one block.

continued

[page 3 of 3]
MICROSCOPIC

1. Sections show fibrous tissue in which there is no significant abnormality.

2. Sections show an encapsulated adrenal tumour comprising cells with large amount of eosinophilic cytoplasm and pleomorphic nuclei forming trabeculae and clustes. There is marked tumour necrosis. Mitoses focally measure up to 18/10 HPF.

Immunoperoxidase studies show staining of the tumour cells for HMB45, inhibin and synaptophysin. There is no staining for cytokeratin and chromogranin A.

The appearances are consistent with an adrenocortical carcinoma.

3. Sections show trabeculae of abnormal cells with focal overlying endothelial cells and organising thrombi. The appearances are consistent with adrenocortical carcinoma.

4. Sections show trabeculae of abnormal cells invading the fibrous tissue.

The appearances are consistent with metastasis from the adrenocortical carcinoma.

5. Sections show nodular fibrous tissue with overlying mesothelium.

The appearances are consistent with organised torted appendix epiploicae.

CONCLUSION

1. Front of duodenum - Fibrous nodule.
2. Right adrenal - Adrenocortical carcinoma.
3. IVC - Adrenocortical carcinoma.
4. Crus of diaphragm - Adrenocortical carcinoma.
5. Transverse colon - Torted appendix epiploicae.

Reported on

Primary Tumour Site Discrepancy		✓
IHPAA Discrepancy		✓

Source: NCI Genomic Data Commons file d2e66a2d-5fbd-4e0f-b1e4-013ebd9d7142 (TCGA-OR-A5JA.6A505565-429B-4D8A-A591-AAB54CF43B66.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).